Somatic mutation profile of tumor specimen d8a5467b-549b-48ed-9ae5-c9c39d (aliquot d8a5467b-549b-48ed-9ae5-c9c39d_D6_1) from CPTAC case 11BR050, project CPTAC-2 (Breast — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Mucinous carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54.0 years (19,709 days).
Specimen d8a5467b-549b-48ed-9ae5-c9c39d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df1ebc45-222e-4a1b-9a69-a46325d1ec7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen d5298917-e497-4c47-a604-645708 (Blood Derived Normal), aliquot d5298917-e497-4c47-a604-645708_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/975d3a11-1ae3-43f0-be53-55d2c73eabcc

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 17, Silent 8, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C6orf132 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 45/374 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); catalogued as rs1398786718; called by muse, mutect2, varscan2
- CCDC142 | c.1885C>T p.R629C (on ENST00000393965 / NM_001365575.2; = p.R622C on NM_032779.4) | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs917657343; called by muse, mutect2
- EXT1 | c.1583G>T p.R528L | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs751404551, COSV100983535, COSV65481604; called by muse, mutect2
- FREM2 | c.7041G>T p.M2347I | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as COSV54832407; called by muse, mutect2
- MTMR11 | c.362G>A p.G121E (on ENST00000439741 / NM_001145862.2; = p.G49E on NM_181873.3) | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs782547156; called by muse, mutect2
- MUC16 | c.26573C>T p.S8858F | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV101201384; called by muse, mutect2
- MUC5B | c.16450G>A p.V5484M | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs752188250, COSV101500234; called by muse, mutect2
- TACC2 | c.7307C>T p.S2436L (on ENST00000334433; = p.S514L on NM_006997.4) | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765550124; called by muse, mutect2
- ATP2B3 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 48/517 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FAT4 | c.4532C>T p.A1511V | Missense Mutation (SNP) | VAF 17/392 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FGFBP2 | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- GBA | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 66/1126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- HJV | c.683A>G p.Q228R (on ENST00000336751 / NM_213653.4; = p.Q115R on NM_145277.5) | Missense Mutation (SNP) | VAF 38/701 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.1); called by muse, mutect2
- LDHAL6B | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 30/504 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- LUZP1 | c.3228C>A p.N1076K | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); called by muse, mutect2
- NPRL3 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- NUFIP2 | c.661C>G p.P221A | Missense Mutation (SNP) | VAF 23/264 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- NUP210L | c.484A>C p.S162R | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TAT | c.1194dup p.E399* | Frame Shift Ins (INS) | VAF 25/222 reads (11%) | called by mutect2, pindel, varscan2
- AMZ2 | c.711T>C p.I237= | Silent (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- ESPNL | c.1350G>A p.K450= | Silent (SNP) | VAF 28/409 reads (7%) | catalogued as rs1230093560; called by muse, mutect2
- JUP | c.507G>A p.L169= | Silent (SNP) | VAF 64/745 reads (9%) | called by muse, mutect2
- KCNJ16 | c.42C>T p.D14= | Silent (SNP) | VAF 19/255 reads (7%) | catalogued as rs148762846, COSV52253062; called by muse, mutect2
- LMX1B | c.330C>T p.L110= | Silent (SNP) | VAF 25/439 reads (6%) | called by muse, mutect2
- LRCH1 | c.276C>T p.P92= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs754934511; called by muse, mutect2
- RYR1 | c.4056G>A p.A1352= | Silent (SNP) | VAF 25/362 reads (7%) | catalogued as rs915321867; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- SYNE2 | c.5178G>A p.K1726= | Silent (SNP) | VAF 26/338 reads (8%) | catalogued as rs1207426888; called by muse, mutect2
